Surgical pathology report (de-identified scan), TCGA case TCGA-2J-AABT, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Mayo Clinic, specimen TCGA-2J-AABT-01A (Primary Tumor).

[page 1 of 3]
Surgery date: Surgical Pathology
REVISED REPORT (Addendum/Procedure included)

ICD-O.3

Adenocarcinoma duct NOS
8500/3
Site: Pancreas head c25.0
7/5/5/14

DIAGNOSIS:

A. Lymph node, hepatic artery, biopsy: A single (1) lymph node is negative for tumor.

B. Common hepatic duct, margin, excision: Negative for tumor.

C. Pancreatic neck, margin, excision: Negative for tumor.

D. Head of pancreas, duodenum, common bile duct, portion jejunum, stent, whipple resection: Invasive moderately differentiated ductal adenocarcinoma is identified forming a solid 4.5 x 4.0 x 2.6 cm mass, situated predominantly within the pancreas. The tumor extends beyond pancreas to involve peripancreatic soft tissue, ampulla of Vater, and the duodenal wall. Tumor necrosis is absent. All surgical resection margins, including the uncinate, pancreatic neck, bile duct, and soft tissue margins, are negative for tumor (minimum tumor-free margin, 0.1 cm, portal vein groove). The adjacent non-neoplastic pancreatic parenchyma shows chronic pancreatitis. A single (1 of 20) regional lymph node is positive for metastatic ductal adenocarcinoma.

AJCC stage (with available surgical material): pT3N1 (7th edition).

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). A revised report will be issued to document the final interpretation after review of the Hematoxylin and Eosin (H&E) permanent sections.

Interpreted by: .

Report electronically signed by

Transcribed by:

ADDENDUM:

Frozen section interpretation has been confirmed by Hematoxylin and Eosin (H&E) permanent section review.

Transcribed by:

Signed by

[page 2 of 3]
GROSS DESCRIPTION:

A. Received fresh labeled "hepatic artery lymph node" is a 3.9 x 1.7 x 0.7 cm lymph node. Lymph node submitted. Grossed by

B. Received fresh labeled "common hepatic duct margin" is a 1.6 x 1.4 x 0.7 cm portion of tan-red tubular tissue with orientation. All submitted. Grossed by

C. Received fresh labeled "pancreatic neck margin" is a 3.2 x 1.3 x 0.9 cm portion of pancreatic tissue with orientation. All submitted. Grossed by

D. Received fresh labeled "head pancreas, duodenum, common bile duct, portion of jejunum, stent" is a Whipple specimen consisting of 29.5 cm in length portion of duodenum, 5.4 x 4.4 x 3.0 cm portion of pancreas. The pancreatic uncinate margin is inked yellow and shaved, the portal vein groove is inked black and submitted perpendicularly. There is a 4.5 x 4.0 x 2.6 cm diffusely infiltrative mass within the pancreas, 0.1 cm from the portal vein groove margin. The mass extends and ulcerates (1.5 x 0.9 cm) the duodenal mucosa. The ulcer is 3.4 cm from the proximal margin. The mass extends to but does not involve the common bile duct. A stent is present within the common bile duct. Peripancreatic lymph nodes and periduodenal lymph nodes are identified. Representative sections are submitted. Grossed by

BLOCK SUMMARY:

Part A: Hepatic artery lymph node

- 1 Hepatic artery LN 1 of 2 (A1)
- 2 Hepatic artery LN 2 of 2 (A1)

Part B: Common hepatic duct margin

- 1 Com hepatic duct margin

Part C: Pancreatic neck margin

- 1 Pancreatic neck margin 1
- 2 Pancreatic neck margin 2

Part D: Head pancreas, duodenum, common bile duct, portion jejunum, stent

- 1 Uncinate margin 1
- 2 Uncinate margin 1
- 3 Uncinate margin 2
- 4 Uncinate margin 2
- 5 Portal vein groove margin
- 6 Ampulla
- 7 Bile duct with tumor
- 8 Pancreas with panc duct
- 9 Duodenum with mass

[page 3 of 3]
- 10 Mass with peripanc ST
- 11 Pancreas mass 1
- 12 Pancreas mass 2
- 13 Peripancreatic LN 5(D1)
- 14 Peripancreatic LN1of2(D2)
- 15 Peripancreatic LN2of2(D2)
- 16 Peripancreatic LN 1(D3)
- 17 Peripancreatic LN 5(D4)
- 18 Peripancreatic LN 2(D5)
- 19 Peripancreatic LN 1(D6)
- 20 Peripancreatic LN2(D7)
- 21 Peripancreatic LN2(D8)

Source: NCI Genomic Data Commons file 5b8f8a89-38ea-46e9-ba5f-b6b3d0e44bfa (TCGA-2J-AABT.8E6CA78A-73D7-4286-88FA-02EB8923DEFD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).